Somatic mutation profile of tumor specimen TCGA-CV-6955-01A (aliquot TCGA-CV-6955-01A-11D-2012-08) from TCGA case TCGA-CV-6955, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 74.6 years (27,261 days).
Specimen TCGA-CV-6955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccd47c7-fda2-404a-bb18-138fd8e34782.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6955-10A (Blood Derived Normal), aliquot TCGA-CV-6955-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da358e1b-76fa-44e5-9fa5-aaa608674c1c

The open-access MAF lists 111 somatic variants for this specimen: 84 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 26, Frame Shift Ins 4, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893811, CM052922, COSV55452571; ClinVar: pathogenic; called by muse, mutect2
- ADAD1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751181043, COSV56641347; called by mutect2, varscan2
- ADGRG4 | c.3304G>T p.A1102S | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV99795285, COSV99797336; called by muse, mutect2
- AGMO | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV100694902; called by muse, mutect2, varscan2
- AOC3 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99520486; called by muse, mutect2, varscan2
- ARFGAP1 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV100796746; called by muse, mutect2, varscan2
- ARHGAP20 | c.2360G>C p.G787A | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV104391026, COSV99505700; called by muse, mutect2
- ARRDC4 | c.661T>C p.C221R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99164566; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- BMERB1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751620582, COSV100253552; called by muse, mutect2, varscan2
- C1orf198 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs749135657, COSV64175387; called by muse, mutect2, varscan2
- CACNA1B | c.5191C>T p.R1731W | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53112622, COSV53129874; called by muse, mutect2, varscan2
- CACNA1D | c.5887G>A p.G1963S (on ENST00000350061 / NM_001128840.3; = p.G1983S on NM_000720.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.166); catalogued as rs769517898, COSV55436569; called by muse, mutect2, varscan2
- CACNA2D1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs1554398049, COSV100667570, COSV62373354; called by muse, mutect2, varscan2
- CELA2A | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100657633, COSV62747368; called by muse, mutect2, varscan2
- CHD8 | c.3721G>A p.A1241T (on ENST00000646647 / NM_001170629.2; = p.A962T on NM_020920.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101303232; called by muse, mutect2, varscan2
- CIT | c.3363C>G p.L1121= | Splice Region (SNP) | VAF 8/156 reads (5%) | catalogued as COSV55868588, COSV55884688, COSV99951307; called by muse, mutect2
- COCH | c.1721T>G p.L574R (on ENST00000216361 / NM_001347720.1; = p.L509R on NM_004086.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364001; called by muse, mutect2, varscan2
- CUL4B | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100341304; called by muse, mutect2, varscan2
- CUX1 | c.1189G>A p.A397T (on ENST00000292535 / NM_181552.4; = p.A408T on NM_001913.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV52912839; called by muse, mutect2, varscan2
- DDX59 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV100494750; called by muse, mutect2
- DIDO1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99827465; called by muse, mutect2
- DPP9 | c.530C>T p.P177L (on ENST00000598800; = p.P206L on NM_139159.5) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779459195, COSV99506611; called by muse, mutect2, varscan2
- EDC4 | c.1877G>T p.S626I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100197821; called by muse, mutect2, varscan2
- EIF2AK1 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99552448; called by muse, mutect2, varscan2
- EVC | c.2218A>G p.M740V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as COSV99382745; called by muse, mutect2, varscan2
- FAT1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 13/137 reads (9%) | catalogued as COSV71672617; called by muse, mutect2
- HDHD5 | c.382G>A p.E128K (on ENST00000336737 / NM_033070.3; = p.E98K on NM_017829.5) | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1457412340, COSV99325093; called by muse, mutect2
- HDX | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99948182; called by muse, mutect2, varscan2
- HSPG2 | c.8380C>T p.R2794W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs755487807, COSV101021400, COSV65972284; called by muse, mutect2, varscan2
- HYDIN | c.13610G>T p.G4537V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101125258; called by muse, mutect2, varscan2
- IBA57 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100812808; called by muse, mutect2
- ITIH4 | c.1513C>A p.L505I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99820042; called by muse, mutect2, varscan2
- KCNA3 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100871326; called by muse, mutect2
- KCNJ8 | c.795G>C p.L265F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557757; called by muse, mutect2, varscan2
- LNX2 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as COSV100310948; called by muse, mutect2, varscan2
- LRP1B | c.9035-1G>C p.X3012_splice | Splice Site (SNP) | VAF 6/74 reads (8%) | catalogued as COSV67183967, COSV67289458; called by muse, mutect2
- LRRC17 | c.1272dup p.H425Tfs*2 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | catalogued as rs745668314; called by mutect2, varscan2
- MIER3 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100423586; called by muse, mutect2
- MYO15A | c.4795A>G p.S1599G | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV99234840; called by muse, mutect2
- MYOCD | c.2382C>G p.I794M | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100591551, COSV58509984; called by muse, mutect2
- NEK5 | c.1469G>T p.R490I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV100839308, COSV100839321; called by muse, mutect2, varscan2
- NOL9 | c.658T>C p.S220P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1465003349, COSV100891540; called by muse, mutect2
- NOTCH1 | c.4558G>C p.D1520H | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99492611; called by muse, mutect2
- NOTCH1 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99492613; called by muse, mutect2, varscan2
- NOTCH1 | c.368_369insA p.E124Gfs*19 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as COSV99492616; called by mutect2, pindel, varscan2
- NREP | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs766863488, COSV99972956; called by muse, mutect2, varscan2
- NSD3 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100395881; called by muse, mutect2
- PCDHGB7 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs369649545; called by muse, mutect2, varscan2
- PEG3 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV99690806; called by muse, mutect2
- PRPF8 | c.4948G>T p.D1650Y | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518041; called by muse, mutect2, varscan2
- PSG1 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99741662; called by muse, mutect2, varscan2
- PSMA1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101123707; called by muse, mutect2, varscan2
- PTCD1 | c.687G>C p.Q229H | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99464687; called by muse, mutect2
- RBBP6 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); catalogued as rs965857051, COSV100155133; called by muse, mutect2, varscan2
- RBBP7 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100418018; called by muse, mutect2
- RBM24 | c.356C>T p.A119V (on ENST00000379052 / NM_001143942.2; = p.A74V on NM_153020.2) | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as COSV100553199; called by muse, mutect2, varscan2
- RGS17 | c.181A>C p.M61L | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424141903, COSV52807976; called by muse, mutect2, varscan2
- RUVBL1 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100494277; called by muse, mutect2, varscan2
- SIRT5 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200008874, COSV100703006; called by mutect2, varscan2
- SLC39A9 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220739; called by muse, mutect2, varscan2
- SOX3 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100983776, COSV65168775; called by muse, mutect2
- SREBF1 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99885277; called by muse, mutect2
- SREBF2 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100761592; called by muse, mutect2, varscan2
- SYNE2 | c.14209G>A p.E4737K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100646860; called by muse, mutect2
- THBS2 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100828143, COSV64682289; called by muse, mutect2, varscan2
- THOC2 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99833308, COSV99834423; called by muse, mutect2, varscan2
- UTRN | c.8670C>G p.F2890L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as COSV100838752; called by muse, mutect2
- UTS2R | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100493419; called by muse, mutect2, varscan2
- ZBTB49 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs868668756, COSV61925663; called by muse, mutect2, varscan2
- ZNF471 | c.1796A>G p.Y599C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1197479447, COSV100340941; called by muse, mutect2, varscan2
- ZNF527 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100648794; called by muse, mutect2, varscan2
- ZSCAN2 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV100306990; called by muse, mutect2
- ZSCAN21 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs555411621, COSV52852833, COSV99460889; called by mutect2, varscan2
- CCDC171 | c.2077_2078insAT p.M693Nfs*5 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by muse*, mutect2
- FAT1 | c.7781_7783del p.P2594del | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- FAT2 | c.6535dup p.R2179Kfs*4 | Frame Shift Ins (INS) | VAF 16/162 reads (10%) | called by mutect2, pindel, varscan2
- FLT3 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MGA | c.9082del p.M3028* (on ENST00000219905 / NM_001164273.1; = p.M2819* on NM_001080541.2) | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
- TAS2R41 | c.555del p.K185Nfs*19 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- TWNK | c.541_544del p.G181Lfs*38 | Frame Shift Del (DEL) | VAF 23/154 reads (15%) | called by mutect2, pindel*, varscan2
- ZNF534 | c.922G>C p.E308Q (on ENST00000332323 / NM_001143939.3; = p.E295Q on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- AHNAK2 | c.9834C>T p.V3278= | Silent (SNP) | VAF 31/280 reads (11%) | catalogued as rs777292646, COSV100319230; called by muse, mutect2, varscan2
- C3orf38 | c.957G>A p.Q319= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100007511; called by muse, mutect2, varscan2
- DMRTB1 | c.855G>A p.P285= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs576142948, COSV65114282; called by muse, mutect2, varscan2
- FAR2 | c.1431C>T p.I477= | Silent (SNP) | VAF 13/239 reads (5%) | catalogued as rs1162267145, COSV51724389, COSV99478711; called by muse, mutect2
- FEZF1 | c.1005C>T p.T335= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100484575; called by muse, mutect2, varscan2
- FSCB | c.1038T>A p.L346= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV100470003; called by muse, mutect2
- FYB2 | c.609C>A p.P203= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100599853; called by muse, mutect2
- IFIT2 | c.738A>T p.V246= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99261120; called by muse, mutect2, varscan2
- LDHC | c.732G>A p.L244= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV99772723; called by muse, mutect2
- MPPED1 | c.600C>T p.T200= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs781362661, COSV101342288; called by muse, mutect2, varscan2
- MYO1C | c.243C>T p.G81= (on ENST00000648651 / NM_001080779.2; = p.G46= on NM_033375.5) | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100704595; called by muse, mutect2
- NLRC5 | c.4425C>T p.L1475= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV99348465; called by muse, mutect2
- OGT | c.2880C>T p.L960= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV101035676; called by muse, mutect2, varscan2
- OR2M3 | c.405C>G p.L135= | Silent (SNP) | VAF 14/279 reads (5%) | catalogued as COSV101513542; called by muse, mutect2
- PCDHGA12 | c.561C>T p.D187= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV52757297; called by muse, mutect2
- PLEKHG5 | c.519C>T p.Y173= (on ENST00000400915 / NM_001042663.3; = p.Y136= on NM_020631.6) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100557224; called by muse, mutect2, varscan2
- RAI2 | c.660C>A p.P220= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100518587; called by muse, mutect2, varscan2
- RNF139 | c.1101C>T p.I367= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as COSV99413783; called by muse, mutect2
- SEC61A2 | c.480G>A p.L160= | Silent (SNP) | VAF 39/379 reads (10%) | catalogued as COSV100036741, COSV53650937, COSV53653529; called by muse, mutect2, varscan2
- SIRT7 | c.666C>T p.G222= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100155799; called by muse, mutect2, varscan2
- SLC35G5 | c.231C>T p.C77= | Silent (SNP) | VAF 31/306 reads (10%) | catalogued as rs148317481; called by muse, mutect2, varscan2
- SOAT2 | c.471C>T p.I157= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100037697; called by muse, mutect2
- SOD3 | c.411G>C p.V137= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101181131; called by muse, mutect2
- TMEM130 | c.1101G>A p.Q367= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs782665906, COSV100229066; called by muse, mutect2, varscan2
- TMPRSS15 | c.1590G>C p.L530= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV53044115, COSV53045368; called by muse, mutect2
- UNC79 | c.3069G>A p.L1023= (on ENST00000393151 / NM_001346218.2; = p.L846= on NM_020818.5) | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as rs545809831, COSV56397369; called by muse, mutect2, varscan2
- MIR222 | n.60G>A | RNA (SNP) | VAF 6/32 reads (19%) | catalogued as rs72631825; called by muse, mutect2, varscan2
